Somatic mutation profile of tumor specimen TCGA-06-2561-01A (aliquot TCGA-06-2561-01A-02D-1494-08) from TCGA case TCGA-06-2561, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.4 years (19,505 days).
Specimen TCGA-06-2561-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 89983652-1ef2-41cb-977b-65043c9c9132.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-2561-10A (Blood Derived Normal), aliquot TCGA-06-2561-10A-01D-1494-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d75c53b6-1182-4c14-ac35-218c79eb71b2

The open-access MAF lists 34 somatic variants for this specimen: 29 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 22, Silent 5, Frame Shift Del 4, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 63/107 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY6 | c.1921C>T p.R641W | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754255254, COSV57168237; called by muse, mutect2, varscan2
- CCDC105 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV52963409; called by muse, mutect2, varscan2
- CLIC5 | c.941C>G p.P314R (on ENST00000185206 / NM_001370649.1; = p.P155R on NM_016929.5) | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV51759661; called by muse, mutect2, varscan2
- CRACD | c.3202C>T p.Q1068* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV51722431; called by muse, mutect2, varscan2
- DNAAF4 | c.8_9del p.L3Pfs*3 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as COSV58249179; called by mutect2, pindel, varscan2
- DNAH3 | c.1075T>C p.F359L | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV54525726; called by muse, mutect2, varscan2
- EGFR | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs774146556, COSV51841003; called by muse, mutect2, varscan2
- FANCD2 | c.2339C>T p.S780L | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); catalogued as COSV55039109; called by muse, mutect2, varscan2
- GOLGA6A | c.1433T>G p.L478R | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV51806872; called by muse, mutect2, varscan2
- INTS6L | c.308G>A p.R103K | Missense Mutation (SNP) | VAF 56/239 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV100878075, COSV66084580; called by muse, mutect2, varscan2
- LIPI | c.151A>G p.K51E | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.959); catalogued as COSV60712106; called by muse, mutect2, varscan2
- MICU1 | c.902G>A p.R301H (on ENST00000361114 / NM_001195518.2; = p.R307H on NM_006077.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs754187624, COSV63145934; called by muse, mutect2, varscan2
- NMRK2 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs749330791, COSV51455539; called by muse, mutect2, varscan2
- OR1B1 | c.724C>T p.R242* | Nonsense Mutation (SNP) | VAF 36/65 reads (55%) | catalogued as rs556567774, COSV59171837; called by muse, mutect2, varscan2
- PIK3CG | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs1370328855, COSV63246438, COSV63251375; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 64/170 reads (38%) | catalogued as rs146650273; called by pindel, varscan2
- PUM1 | c.3304T>G p.C1102G | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV57086204; called by muse, mutect2, varscan2
- SAGE1 | c.2125T>A p.C709S | Missense Mutation (SNP) | VAF 94/307 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61014065; called by muse, mutect2, varscan2
- SNAP91 | c.2435C>T p.A812V | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.254); catalogued as COSV52132471; called by muse, mutect2, varscan2
- SPAG5 | c.2215C>G p.L739V | Missense Mutation (SNP) | VAF 110/428 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV58802057; called by muse, mutect2, varscan2
- SRGAP3 | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 27/109 reads (25%) | catalogued as COSV100841527, COSV64534037; called by muse, mutect2, varscan2
- STAG2 | c.2025G>C p.E675D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV54360134; called by muse, mutect2, varscan2
- TTN | c.10143C>A p.D3381E (on ENST00000591111; = p.D3335E on NM_003319.4) | Missense Mutation (SNP) | VAF 43/172 reads (25%) | PolyPhen benign (0.007); catalogued as COSV60300798; called by muse, mutect2, varscan2
- XRCC5 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV67536428; called by muse, mutect2, varscan2
- ZNF208 | c.2344T>G p.C782G | Missense Mutation (SNP) | VAF 45/156 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as COSV68111761; called by muse, mutect2, varscan2
- CREB1 | c.470_474del p.E157Gfs*20 (on ENST00000432329 / NM_134442.5; = p.E143Gfs*20 on NM_004379.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 41/151 reads (27%) | called by mutect2, pindel, varscan2
- HNF1B | c.1250C>T p.T417M | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MLLT3 | c.335del p.P112Hfs*3 | Frame Shift Del (DEL) | VAF 96/230 reads (42%) | called by mutect2, pindel, varscan2
- FBXL20 | c.753C>A p.S251= | Silent (SNP) | VAF 20/162 reads (12%) | catalogued as rs770647171, COSV52903618; called by muse, mutect2, varscan2
- MEN1 | c.480C>T p.S160= | Silent (SNP) | VAF 3/39 reads (8%) | catalogued as rs936786553, COSV53643666; ClinVar: likely benign; called by muse, mutect2
- MTNR1B | c.897C>T p.F299= | Silent (SNP) | VAF 179/563 reads (32%) | catalogued as COSV57066766; called by muse, mutect2, varscan2
- NUDT11 | c.177C>T p.G59= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV65664950; called by muse, mutect2, varscan2
- TTLL13P | c.1233C>T p.L411= | Silent (SNP) | VAF 9/217 reads (4%) | catalogued as COSV60039841; called by muse, mutect2
